Somatic mutation profile of tumor specimen TCGA-DU-6397-02A (aliquot TCGA-DU-6397-02A-12D-A36O-08) from TCGA case TCGA-DU-6397, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 45.7 years (16,695 days).
Specimen TCGA-DU-6397-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17c99bf3-a124-4c85-b410-e8f13e83d0c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6397-10A (Blood Derived Normal), aliquot TCGA-DU-6397-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86870c41-b661-4f7b-af72-cea863cc75fb

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Frame Shift Del 17, Silent 10, In Frame Del 5, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 52/113 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- ABCB4 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99711381; called by mutect2, varscan2
- ANO3 | c.2576+1G>C p.X859_splice | Splice Site (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99886021; called by mutect2, varscan2
- CD86 | c.446A>C p.E149A (on ENST00000330540 / NM_175862.5; = p.E143A on NM_006889.4) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as rs774925932, COSV100054229; called by mutect2, varscan2
- COLGALT2 | c.794A>C p.D265A | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100730897; called by muse, mutect2, varscan2
- DYRK2 | c.1742C>T p.A581V (on ENST00000344096 / NM_006482.3; = p.A508V on NM_003583.4) | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs749972090, COSV59845798; called by mutect2, varscan2
- F5 | c.6088A>G p.N2030D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100889265; called by mutect2, varscan2
- GPR18 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100540675; called by muse, mutect2, varscan2
- KRI1 | c.1403G>C p.R468P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.129); catalogued as COSV100470489; called by mutect2, varscan2
- MED26 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs911083953, COSV54660782; called by mutect2, varscan2
- MYH7B | c.5455_5457del p.K1819del | In Frame Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs780550114; called by pindel, varscan2
- NBAS | c.96G>T p.W32C | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99871829; called by muse, mutect2, varscan2
- NOTCH1 | c.6307G>T p.E2103* | Nonsense Mutation (SNP) | VAF 31/49 reads (63%) | catalogued as rs1253251665, COSV99492226; called by mutect2, varscan2
- OR5AC2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs755877682, COSV62279133; called by muse, mutect2
- OR8A1 | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV99420882; called by mutect2, varscan2
- RUFY2 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56260461; called by muse, mutect2, varscan2
- SPIC | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100163087; called by mutect2, varscan2
- SWAP70 | c.305dup p.N102Kfs*16 | Frame Shift Ins (INS) | VAF 42/161 reads (26%) | catalogued as rs749995893; called by mutect2, varscan2
- TBXA2R | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1389139150, COSV64343669; called by mutect2, varscan2
- TIAM2 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.474); catalogued as COSV100020295; called by muse, mutect2, varscan2
- TIAM2 | c.2552G>T p.G851V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.109); catalogued as COSV100020297; called by muse, mutect2, varscan2
- TP53BP1 | c.3919_3921del p.S1307del | In Frame Del (DEL) | VAF 50/142 reads (35%) | catalogued as rs1248458809; called by pindel, varscan2
- VAV1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs769393831, COSV58382329; called by muse, mutect2, varscan2
- YBX2 | c.686_688del p.F229del | In Frame Del (DEL) | VAF 94/247 reads (38%) | catalogued as rs751339230; called by pindel, varscan2
- ASPM | c.1109_1110del p.S370Ffs*5 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ATRIP | c.1424_1425del p.S475Cfs*5 | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | called by pindel, varscan2
- BICC1 | c.1194_1195del p.S399Cfs*2 | Frame Shift Del (DEL) | VAF 50/124 reads (40%) | called by mutect2, pindel, varscan2
- CIC | c.2278_2279del p.V760Hfs*2 | Frame Shift Del (DEL) | VAF 14/22 reads (64%) | called by mutect2, pindel, varscan2
- COA7 | c.94_96del p.K32del | In Frame Del (DEL) | VAF 32/51 reads (63%) | called by mutect2, pindel, varscan2
- EPHA7 | c.1359_1360del p.R453Sfs*24 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | called by pindel, varscan2
- FAM160B1 | c.1581_1583del p.E527del | In Frame Del (DEL) | VAF 26/82 reads (32%) | called by pindel, varscan2
- FUBP1 | c.11_12del p.Y4Ffs*24 | Frame Shift Del (DEL) | VAF 22/35 reads (63%) | called by mutect2, pindel, varscan2
- GINS2 | c.535_536del p.S179Yfs*20 | Frame Shift Del (DEL) | VAF 37/118 reads (31%) | called by pindel, varscan2
- GLB1 | c.887_891del p.I296Sfs*37 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- GPR22 | c.925_928del p.K309Efs*8 | Frame Shift Del (DEL) | VAF 51/135 reads (38%) | called by mutect2, pindel, varscan2
- GRIK2 | c.1885_1892del p.K629Vfs*23 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- HDGF | c.543_544dup p.A182Gfs*144 | Frame Shift Ins (INS) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- HSPA1L | c.1318del p.V440Cfs*2 | Frame Shift Del (DEL) | VAF 71/251 reads (28%) | called by mutect2, pindel, varscan2
- IGF1R | c.3895_3905del p.N1299Rfs*71 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- LARS1 | c.3188_3192del p.I1063Tfs*22 (on ENST00000394434 / NM_020117.11; = p.I1036Tfs*22 on NM_016460.3) | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by pindel, varscan2
- RFX3 | c.2061_2062del p.S688Rfs*74 | Frame Shift Del (DEL) | VAF 27/39 reads (69%) | called by mutect2, pindel, varscan2
- SPINT1 | c.1271del p.C424Ffs*29 (on ENST00000344051 / NM_181642.3; = p.C408Ffs*29 on NM_003710.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 55/167 reads (33%) | called by mutect2, pindel, varscan2
- XYLB | c.680_681del p.K227Sfs*19 | Frame Shift Del (DEL) | VAF 72/266 reads (27%) | called by mutect2, pindel, varscan2
- YIF1A | c.269_270del p.K90Tfs*35 | Frame Shift Del (DEL) | VAF 48/202 reads (24%) | called by mutect2, pindel, varscan2
- ASXL3 | c.5466G>A p.K1822= | Silent (SNP) | VAF 99/234 reads (42%) | catalogued as rs779348506, COSV99326806; called by muse, mutect2, varscan2
- CACNA1G | c.6645A>G p.L2215= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV61733226; called by mutect2, varscan2
- CTDSPL2 | c.1332A>G p.E444= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs1196373979, COSV99527269; called by muse, mutect2, varscan2
- DPEP3 | c.279C>A p.L93= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs531603108, COSV52051554, COSV99262927; called by muse, mutect2
- FRY | c.747G>A p.A249= | Silent (SNP) | VAF 52/95 reads (55%) | catalogued as rs763898329, COSV66568856; called by mutect2, varscan2
- HMCN1 | c.12726C>T p.N4242= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs150757082; called by muse, mutect2, varscan2
- MYLK | c.162G>A p.G54= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100659715; called by mutect2, varscan2
- RETNLB | c.117C>A p.L39= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV55466036, COSV99848847; called by mutect2, varscan2
- RIPOR1 | c.567C>T p.R189= (on ENST00000379312 / NM_001193522.2; = p.R185= on NM_024519.4) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs371091978; called by muse, mutect2, varscan2
- ZNF446 | c.588A>G p.Q196= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99543515; called by mutect2, varscan2
- C1orf216 | chr1:35720916 C>A | 5'Flank (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99231594; called by mutect2, varscan2
